Somatic mutation profile of tumor specimen HCM-BROD-0220-C15-06A (aliquot HCM-BROD-0220-C15-06A-11D-A79C-36) from HCMI case HCM-BROD-0220-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: GX; Age at diagnosis: 60.2 years (21,985 days).
Specimen HCM-BROD-0220-C15-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e4e4aa3b-b19a-4a0f-88d8-4c0bfbc1562e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0220-C15-10A (Blood Derived Normal), aliquot HCM-BROD-0220-C15-10A-01D-A79C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/669a5cb5-dd23-4f17-9fb7-717a291b7725

The open-access MAF lists 209 somatic variants for this specimen: 150 protein-altering or splice-affecting, 50 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 138, Silent 50, Intron 5, Frame Shift Del 4, Nonsense Mutation 4, 5'Flank 2, Splice Region 1, Frame Shift Ins 1, 3'Flank 1, In Frame Del 1, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.83_100del p.V28_E33del | In Frame Del (DEL) | VAF 124/326 reads (38%) | hotspot (GDC flag); called by pindel, varscan2
- TP53 | c.820G>T p.V274F | Missense Mutation (SNP) | VAF 294/339 reads (87%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.496); catalogued as rs1057520005, COSV52707923, COSV52708386, COSV52728497, COSV53727597; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC4 | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 143/711 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV65313251; called by muse, mutect2, varscan2
- ADAM29 | c.839G>A p.R280Q | Missense Mutation (SNP) | VAF 90/218 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs765339011, COSV63660350; called by muse, mutect2, varscan2
- ADAM30 | c.787C>T p.R263C | Missense Mutation (SNP) | VAF 216/246 reads (88%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.915); catalogued as rs200088734, COSV65561660; called by muse, mutect2, varscan2
- ADAMTS3 | c.3439G>A p.V1147I | Missense Mutation (SNP) | VAF 103/266 reads (39%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); catalogued as rs759487867, COSV54390590; called by muse, mutect2, varscan2
- ADCY2 | c.2656G>A p.V886I | Missense Mutation (SNP) | VAF 147/357 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as rs326146, COSV57901415; called by muse, mutect2, varscan2
- AKAP6 | c.728T>C p.M243T | Missense Mutation (SNP) | VAF 13/267 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as rs1422797309; called by muse, mutect2
- ANKRD30B | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 38/143 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as rs761682028, COSV100746671; called by muse, mutect2, varscan2
- AP002512.3 | c.367C>A p.R123S | Missense Mutation (SNP) | VAF 108/418 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.421); catalogued as rs772474039, COSV54406603; called by muse, mutect2, varscan2
- ARID3A | c.631G>A p.V211I | Missense Mutation (SNP) | VAF 200/460 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as rs577924521; called by muse, varscan2
- ASIC5 | c.440A>T p.N147I | Missense Mutation (SNP) | VAF 109/274 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as COSV101539702; called by muse, mutect2, varscan2
- AXL | c.922C>T p.R308C | Missense Mutation (SNP) | VAF 143/402 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs1306116384, COSV56568438; called by muse, mutect2, varscan2
- C10orf71 | c.4112G>A p.R1371H | Missense Mutation (SNP) | VAF 148/514 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs576453887, COSV60511789; called by muse, mutect2, varscan2
- C11orf87 | c.182C>T p.T61M | Missense Mutation (SNP) | VAF 130/512 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs187108020, COSV59356856; called by muse, mutect2, varscan2
- COL24A1 | c.4230del p.D1412Mfs*28 | Frame Shift Del (DEL) | VAF 44/149 reads (30%) | catalogued as COSV65302287; called by mutect2, pindel, varscan2
- CWC22 | c.338C>T p.P113L | Missense Mutation (SNP) | VAF 70/306 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.758); catalogued as rs1306263212; called by muse, mutect2, varscan2
- DCLRE1C | c.448C>G p.L150V (on ENST00000378278 / NM_001350965.2; = p.L35V on NM_022487.4) | Missense Mutation (SNP) | VAF 12/342 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as COSV63184889; called by muse, mutect2
- DNAH11 | c.6985T>C p.Y2329H | Missense Mutation (SNP) | VAF 140/2552 reads (5%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.967); catalogued as COSV60939155; called by muse, mutect2
- DYTN | c.403G>T p.E135* | Nonsense Mutation (SNP) | VAF 92/309 reads (30%) | catalogued as COSV65970515; called by muse, mutect2, varscan2
- FAM120B | c.499G>A p.G167S | Missense Mutation (SNP) | VAF 23/476 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1427933888; called by muse, mutect2
- FARSB | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 162/285 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as rs767956337, COSV56051949; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- FBRSL1 | c.1675C>T p.R559W | Missense Mutation (SNP) | VAF 294/496 reads (59%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1287979091; called by muse, mutect2, varscan2
- FBXL20 | c.1211T>C p.L404S | Missense Mutation (SNP) | VAF 1387/4607 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.303); catalogued as COSV99060050; called by muse, mutect2, varscan2
- FN1 | c.5345T>C p.L1782P | Missense Mutation (SNP) | VAF 59/173 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60547816; called by muse, mutect2, varscan2
- GIMAP4 | c.146G>C p.S49T | Missense Mutation (SNP) | VAF 88/296 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.216); catalogued as rs1428397783; called by muse, mutect2, varscan2
- GRIK1 | c.464C>A p.A155E | Missense Mutation (SNP) | VAF 94/228 reads (41%) | SIFT tolerated (0.54); PolyPhen benign (0.232); catalogued as rs1177067242, COSV58711534; called by muse, mutect2, varscan2
- IKZF1 | c.33A>C p.Q11H | Missense Mutation (SNP) | VAF 112/663 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.172); catalogued as rs1480100906; called by muse, mutect2, varscan2
- IRX2 | c.218C>A p.A73D | Missense Mutation (SNP) | VAF 30/752 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.134); catalogued as rs968302962; called by muse, mutect2
- JAK1 | c.1798G>T p.G600W | Missense Mutation (SNP) | VAF 104/272 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61096327; called by muse, mutect2, varscan2
- KCNA6 | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 137/575 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV99768939; called by muse, mutect2, varscan2
- KIAA1109 | c.1604C>T p.A535V | Missense Mutation (SNP) | VAF 57/154 reads (37%) | SIFT tolerated (1); PolyPhen probably damaging (0.985); catalogued as rs1291063022; called by muse, mutect2, varscan2
- KRT17 | c.448G>A p.V150M | Missense Mutation (SNP) | VAF 182/2426 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.067); catalogued as rs755542251; called by muse, mutect2
- L3MBTL1 | c.605C>A p.P202Q (on ENST00000418998 / NM_001377303.1; = p.P112Q on NM_015478.7) | Missense Mutation (SNP) | VAF 120/533 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.359); catalogued as COSV64233573; called by muse, mutect2, varscan2
- LAMA1 | c.2266G>A p.V756I | Missense Mutation (SNP) | VAF 64/308 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.026); catalogued as rs776368738, COSV67541780; called by muse, mutect2, varscan2
- LAMA1 | c.1745C>T p.A582V | Missense Mutation (SNP) | VAF 197/311 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as rs780440007, COSV67531188; called by muse, mutect2, varscan2
- LBX2 | c.535G>A p.G179S (on ENST00000377566 / NM_001282430.2; = p.G175S on NM_001009812.2) | Missense Mutation (SNP) | VAF 271/477 reads (57%) | SIFT tolerated (0.75); PolyPhen benign (0.019); catalogued as rs777056738; called by muse, mutect2, varscan2
- LILRB4 | c.601T>G p.F201V | Missense Mutation (SNP) | VAF 150/354 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.098); catalogued as COSV54409361; called by muse, mutect2, varscan2
- LRIT1 | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 105/397 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.12); catalogued as COSV100928200; called by muse, mutect2, varscan2
- MGRN1 | c.1174C>T p.L392F | Missense Mutation (SNP) | VAF 13/440 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1248791454; called by muse, mutect2
- MYRF | c.316G>A p.G106S (on ENST00000278836 / NM_001127392.3; = p.G97S on NM_013279.4) | Missense Mutation (SNP) | VAF 182/701 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.132); catalogued as rs143154821; called by muse, mutect2, varscan2
- NEO1 | c.2327G>A p.G776D | Missense Mutation (SNP) | VAF 96/252 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1567628993; called by muse, mutect2, varscan2
- OR10R2 | c.241T>G p.F81V | Missense Mutation (SNP) | VAF 98/358 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as rs1008730168; called by muse, mutect2, varscan2
- OR8U1 | c.94T>G p.L32V | Missense Mutation (SNP) | VAF 106/426 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as rs1384529091, COSV56414040, COSV56416675; called by muse, varscan2
- PCLO | c.13009A>T p.T4337S | Missense Mutation (SNP) | VAF 18/207 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.356); catalogued as COSV61657892; called by muse, mutect2
- PHIP | c.499A>G p.T167A | Missense Mutation (SNP) | VAF 111/256 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.344); catalogued as rs748247534; called by muse, mutect2, varscan2
- PTK2B | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 110/259 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as rs765936240; called by muse, mutect2, varscan2
- RLF | c.638C>T p.S213F | Missense Mutation (SNP) | VAF 18/214 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1475197866; called by muse, mutect2
- RYR2 | c.430G>T p.A144S | Missense Mutation (SNP) | VAF 124/324 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.145); catalogued as COSV63683406; called by muse, mutect2, varscan2
- SEMA6D | c.1801G>A p.A601T | Missense Mutation (SNP) | VAF 68/154 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs764064628; called by muse, mutect2, varscan2
- SLITRK4 | c.2227A>G p.I743V | Missense Mutation (SNP) | VAF 21/286 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.039); catalogued as rs781826673; called by muse, mutect2
- SLITRK4 | c.701A>C p.N234T | Missense Mutation (SNP) | VAF 99/225 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as COSV100567598; called by muse, mutect2, varscan2
- TBPL2 | c.427G>A p.G143R | Missense Mutation (SNP) | VAF 95/264 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as rs368981752; called by muse, mutect2, varscan2
- TCERG1 | c.1985G>A p.R662Q | Missense Mutation (SNP) | VAF 86/271 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1303714163; called by muse, mutect2, varscan2
- TRIM2 | c.1582C>T p.R528C (on ENST00000437508; = p.R555C on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 99/269 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58635738; called by muse, mutect2, varscan2
- VN1R4 | c.160T>C p.F54L | Missense Mutation (SNP) | VAF 76/201 reads (38%) | SIFT tolerated (0.7); PolyPhen benign (0.005); catalogued as COSV60805387; called by muse, mutect2, varscan2
- ZBTB46 | c.902C>T p.P301L | Missense Mutation (SNP) | VAF 100/510 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs568344981; called by muse, mutect2, varscan2
- ZFHX4 | c.872G>T p.R291M | Missense Mutation (SNP) | VAF 178/407 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50620924; called by muse, mutect2, varscan2
- ABCA13 | c.13078C>G p.P4360A | Missense Mutation (SNP) | VAF 60/520 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ABCA9 | c.3665G>T p.C1222F | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ADA2 | c.452C>A p.P151Q | Missense Mutation (SNP) | VAF 83/209 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ANK3 | c.7068A>C p.K2356N | Missense Mutation (SNP) | VAF 22/312 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ARHGAP15 | c.598A>T p.R200* | Nonsense Mutation (SNP) | VAF 42/101 reads (42%) | called by muse, mutect2, varscan2
- BCHE | c.1271A>G p.Y424C | Missense Mutation (SNP) | VAF 11/402 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2
- C5orf38 | c.164G>T p.G55V | Missense Mutation (SNP) | VAF 250/627 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- C6orf226 | c.230T>A p.I77K | Missense Mutation (SNP) | VAF 142/500 reads (28%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- CADM1 | c.793T>G p.L265V | Missense Mutation (SNP) | VAF 68/242 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CAPN6 | c.1876G>T p.G626C | Missense Mutation (SNP) | VAF 106/250 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CARS2 | c.1273G>A p.G425S | Missense Mutation (SNP) | VAF 183/518 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCDC107 | c.812C>G p.T271R | Missense Mutation (SNP) | VAF 78/199 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CD8A | c.452C>A p.T151N | Missense Mutation (SNP) | VAF 163/613 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- CDKN2A | c.37_40dup p.D14Gfs*2 | Nonsense Mutation (INS) | VAF 154/322 reads (48%) | called by pindel, varscan2
- CDRT1 | c.1847A>C p.K616T | Missense Mutation (SNP) | VAF 68/277 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- CENPJ | c.2602A>C p.K868Q | Missense Mutation (SNP) | VAF 62/302 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- CHD4 | c.773G>C p.R258P | Missense Mutation (SNP) | VAF 57/241 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- CNTN1 | c.943A>G p.I315V | Missense Mutation (SNP) | VAF 45/207 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- COL6A6 | c.4201G>A p.G1401R | Missense Mutation (SNP) | VAF 70/185 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CPT1A | c.1421C>T p.S474F | Missense Mutation (SNP) | VAF 131/389 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CSMD1 | c.7324G>T p.G2442W (on ENST00000520002; = p.G2441W on NM_033225.6) | Missense Mutation (SNP) | VAF 22/286 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CSMD1 | c.3492A>C p.K1164N (on ENST00000520002; = p.K1163N on NM_033225.6) | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.997); called by muse, mutect2
- CYSRT1 | c.445G>A p.G149R (on ENST00000409414; = p.G109R on NM_199001.5) | Missense Mutation (SNP) | VAF 210/531 reads (40%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- DCDC1 | c.2456A>C p.N819T | Missense Mutation (SNP) | VAF 66/234 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DCHS1 | c.6041A>G p.D2014G | Missense Mutation (SNP) | VAF 224/386 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- DHX34 | c.1552C>T p.P518S | Missense Mutation (SNP) | VAF 12/347 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DNAH9 | c.10651C>A p.L3551I | Missense Mutation (SNP) | VAF 67/271 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- DST | c.1432A>C p.N478H (on ENST00000361203 / NM_001374722.1; = p.N152H on NM_001723.6) | Missense Mutation (SNP) | VAF 68/279 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- EEF1AKNMT | c.1979T>A p.L660H (on ENST00000361735 / NM_015935.5; = p.L574H on NM_014955.3) | Missense Mutation (SNP) | VAF 112/392 reads (29%) | SIFT tolerated (0.55); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ELP4 | c.186_207del p.V63* | Frame Shift Del (DEL) | VAF 56/314 reads (18%) | called by mutect2, pindel, varscan2
- EPHA6 | c.2794dup p.I932Nfs*45 | Frame Shift Ins (INS) | VAF 55/160 reads (34%) | called by mutect2, pindel, varscan2
- FAM135B | c.2900C>G p.A967G | Missense Mutation (SNP) | VAF 193/500 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM83H | c.293_318del p.V98Afs*2 | Frame Shift Del (DEL) | VAF 348/1200 reads (29%) | called by mutect2, pindel, varscan2
- FASN | c.5558T>A p.V1853D | Missense Mutation (SNP) | VAF 102/255 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- GALNT14 | c.615C>A p.N205K | Missense Mutation (SNP) | VAF 75/301 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GIMAP2 | c.577G>A p.D193N | Missense Mutation (SNP) | VAF 100/318 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- GNAS | c.473C>A p.P158Q | Missense Mutation (SNP) | VAF 92/523 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- GPM6A | c.608A>T p.E203V | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPR155 | c.1268C>T p.S423F | Missense Mutation (SNP) | VAF 31/259 reads (12%) | SIFT tolerated (0.94); PolyPhen benign (0); called by muse, mutect2, varscan2
- GYPB | c.131C>G p.T44R | Missense Mutation (SNP) | VAF 133/268 reads (50%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- HAPLN2 | c.431G>A p.S144N | Missense Mutation (SNP) | VAF 91/329 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HOOK2 | c.589C>A p.L197M | Missense Mutation (SNP) | VAF 87/212 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HOXA13 | c.503C>A p.A168E | Missense Mutation (SNP) | VAF 426/5504 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); called by muse, mutect2
- HPS3 | c.898G>A p.D300N | Missense Mutation (SNP) | VAF 23/244 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- IGKV3D-11 | c.303A>C p.E101D | Missense Mutation (SNP) | VAF 85/316 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- ILDR2 | c.1604G>A p.R535H | Missense Mutation (SNP) | VAF 209/687 reads (30%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- INO80 | c.1003C>T p.R335C | Missense Mutation (SNP) | VAF 105/259 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- KCNK2 | c.793A>C p.T265P (on ENST00000444842 / NM_001017425.3; = p.T250P on NM_014217.4) | Missense Mutation (SNP) | VAF 54/226 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNN2 | c.1585A>G p.S529G (on ENST00000264773; = p.S741G on NM_021614.4) | Missense Mutation (SNP) | VAF 113/300 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- KLRD1 | c.337C>A p.Q113K | Missense Mutation (SNP) | VAF 68/248 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KRT33B | c.580C>T p.H194Y | Missense Mutation (SNP) | VAF 90/2923 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KRT9 | c.1390G>A p.D464N | Missense Mutation (SNP) | VAF 152/1786 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2
- KRTAP10-8 | c.280T>A p.C94S | Missense Mutation (SNP) | VAF 169/438 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- KRTAP29-1 | c.965G>T p.C322F | Missense Mutation (SNP) | VAF 408/6068 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); called by muse, mutect2
- L3MBTL1 | c.604C>T p.P202S (on ENST00000418998 / NM_001377303.1; = p.P112S on NM_015478.7) | Missense Mutation (SNP) | VAF 119/538 reads (22%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- LAMA1 | c.7120A>T p.I2374F | Missense Mutation (SNP) | VAF 24/449 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.057); called by muse, mutect2
- LARP1 | c.784G>A p.E262K (on ENST00000518297 / NM_033551.3; = p.E185K on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 82/290 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.079); called by muse, varscan2
- LILRB4 | c.319T>C p.S107P | Missense Mutation (SNP) | VAF 120/301 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- LMCD1 | c.785C>A p.A262E | Missense Mutation (SNP) | VAF 144/342 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- LRCH1 | c.1151C>T p.P384L | Missense Mutation (SNP) | VAF 168/367 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MACROH2A1 | c.788G>A p.S263N (on ENST00000510038; = p.S262N on NM_004893.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/215 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- MORC3 | c.1104-1G>C p.X368_splice | Splice Site (SNP) | VAF 41/90 reads (46%) | called by muse, mutect2, varscan2
- MSH4 | c.934del p.I312* | Frame Shift Del (DEL) | VAF 69/186 reads (37%) | called by mutect2, pindel, varscan2
- MTMR9 | c.1492T>C p.F498L | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- NEMP2 | c.951G>A p.R317= | Splice Region (SNP) | VAF 39/118 reads (33%) | called by muse, mutect2, varscan2
- NEUROD6 | c.428T>C p.I143T | Missense Mutation (SNP) | VAF 83/546 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- NKX6-2 | c.217G>A p.G73R | Missense Mutation (SNP) | VAF 216/742 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- NUFIP2 | c.1978G>T p.A660S | Missense Mutation (SNP) | VAF 7/144 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.865); called by muse, mutect2
- NUP205 | c.5836C>G p.L1946V | Missense Mutation (SNP) | VAF 93/296 reads (31%) | SIFT tolerated (0.43); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- OBSCN | c.22794C>G p.S7598R | Missense Mutation (SNP) | VAF 82/271 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- OR5B21 | c.103A>T p.I35F | Missense Mutation (SNP) | VAF 118/387 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- OTOGL | c.6102T>A p.C2034* (on ENST00000547103; = p.C2025* on NM_173591.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 51/186 reads (27%) | called by muse, mutect2, varscan2
- PGBD2 | c.1633A>G p.S545G | Missense Mutation (SNP) | VAF 92/387 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- PLCB3 | c.2456G>C p.G819A | Missense Mutation (SNP) | VAF 106/403 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PPARG | c.896A>G p.Q299R (on ENST00000287820 / NM_015869.5; = p.Q269R on NM_005037.7) | Missense Mutation (SNP) | VAF 101/234 reads (43%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- PXN | c.1765C>T p.L589F (on ENST00000228307 / NM_001080855.3; = p.L555F on NM_002859.4) | Missense Mutation (SNP) | VAF 61/241 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RHBDD2 | c.100C>A p.P34T | Missense Mutation (SNP) | VAF 127/361 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RIMBP2 | c.2788T>C p.F930L | Missense Mutation (SNP) | VAF 59/221 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- RUVBL2 | c.1307A>G p.E436G | Missense Mutation (SNP) | VAF 110/288 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- SBF2 | c.3040G>T p.A1014S | Missense Mutation (SNP) | VAF 112/391 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- SCGB1C1 | c.97T>G p.F33V | Missense Mutation (SNP) | VAF 47/356 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, varscan2
- SGCZ | c.794C>G p.S265C | Missense Mutation (SNP) | VAF 79/209 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.518); called by muse, mutect2, varscan2
- SLC12A9 | c.930C>A p.F310L | Missense Mutation (SNP) | VAF 103/225 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- SRCIN1 | c.2042G>T p.R681L (on ENST00000621492; = p.R647L on NM_025248.3) | Missense Mutation (SNP) | VAF 376/3393 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- TCEAL5 | c.560T>G p.V187G | Missense Mutation (SNP) | VAF 132/424 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TENM1 | c.3592G>T p.V1198F | Missense Mutation (SNP) | VAF 186/213 reads (87%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- TENM2 | c.4064T>A p.L1355Q (on ENST00000518659 / NM_001122679.2; = p.L1116Q on NM_001080428.3) | Missense Mutation (SNP) | VAF 43/158 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TOP2B | c.2287G>C p.V763L (on ENST00000264331 / NM_001330700.2; = p.V758L on NM_001068.3) | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.53); called by muse, mutect2
- TRIM49C | c.37C>A p.L13I | Missense Mutation (SNP) | VAF 12/252 reads (5%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.483); called by muse, mutect2
- UBAP2L | c.1996C>G p.L666V | Missense Mutation (SNP) | VAF 114/393 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- VPS51 | c.160G>T p.G54W | Missense Mutation (SNP) | VAF 45/600 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); called by muse, mutect2
- ZNF692 | c.56A>C p.Q19P | Missense Mutation (SNP) | VAF 190/848 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- ABCC5 | c.4071A>C p.T1357= | Silent (SNP) | VAF 136/234 reads (58%) | called by muse, varscan2
- ADAM2 | c.2169C>T p.S723= | Silent (SNP) | VAF 41/115 reads (36%) | catalogued as rs751986797; called by muse, mutect2, varscan2
- ATP7A | c.1440C>T p.D480= | Silent (SNP) | VAF 105/241 reads (44%) | called by muse, mutect2, varscan2
- BCL11A | c.270C>T p.I90= | Silent (SNP) | VAF 82/315 reads (26%) | catalogued as rs1446265434; called by muse, mutect2, varscan2
- C5orf38 | c.165G>T p.G55= | Silent (SNP) | VAF 224/573 reads (39%) | called by muse, varscan2
- C6 | c.1608G>T p.G536= | Silent (SNP) | VAF 108/639 reads (17%) | catalogued as rs1194069643; called by muse, mutect2, varscan2
- CALCRL | c.609C>A p.A203= | Silent (SNP) | VAF 95/185 reads (51%) | catalogued as COSV66476652; called by muse, mutect2, varscan2
- CASC3 | c.204C>T p.G68= | Silent (SNP) | VAF 126/2210 reads (6%) | called by muse, mutect2
- CBFA2T3 | c.111C>T p.A37= | Silent (SNP) | VAF 123/446 reads (28%) | catalogued as rs527797742, COSV51932421; called by muse, mutect2, varscan2
- CDRT15L2 | c.300G>A p.A100= | Silent (SNP) | VAF 181/215 reads (84%) | catalogued as rs1266472474; called by muse, mutect2, varscan2
- DHH | c.618G>T p.V206= | Silent (SNP) | VAF 180/547 reads (33%) | called by mutect2, varscan2
- DMXL2 | c.3645T>G p.T1215= | Silent (SNP) | VAF 101/266 reads (38%) | catalogued as COSV51845749; called by muse, mutect2, varscan2
- DNAAF4 | c.1173G>C p.A391= | Silent (SNP) | VAF 33/86 reads (38%) | called by muse, mutect2, varscan2
- ETV3L | c.564A>G p.P188= | Silent (SNP) | VAF 99/336 reads (29%) | called by muse, mutect2, varscan2
- FAM181B | c.156G>A p.S52= | Silent (SNP) | VAF 188/662 reads (28%) | catalogued as rs1302146256, COSV100235094; called by muse, mutect2, varscan2
- FRA10AC1 | c.864A>G p.E288= | Silent (SNP) | VAF 148/280 reads (53%) | called by muse, mutect2, varscan2
- HERC1 | c.14415G>T p.L4805= | Silent (SNP) | VAF 84/197 reads (43%) | called by muse, mutect2, varscan2
- IFT140 | c.3912C>T p.H1304= | Silent (SNP) | VAF 119/401 reads (30%) | catalogued as rs143385994; called by muse, mutect2, varscan2
- IL12RB2 | c.2334G>A p.K778= | Silent (SNP) | VAF 287/349 reads (82%) | called by muse, mutect2, varscan2
- IL34 | c.57G>A p.L19= | Silent (SNP) | VAF 85/286 reads (30%) | called by muse, mutect2, varscan2
- IQCH | c.1125G>A p.K375= | Silent (SNP) | VAF 114/322 reads (35%) | called by muse, mutect2, varscan2
- ISM1 | c.1227G>A p.E409= | Silent (SNP) | VAF 96/422 reads (23%) | catalogued as rs761644256; called by muse, mutect2, varscan2
- LSS | c.54C>T p.P18= | Silent (SNP) | VAF 123/321 reads (38%) | called by muse, mutect2, varscan2
- MFAP3 | c.522C>T p.S174= | Silent (SNP) | VAF 54/156 reads (35%) | catalogued as rs755554678; called by muse, varscan2
- MORC1 | c.1383C>T p.I461= | Silent (SNP) | VAF 41/134 reads (31%) | catalogued as rs758284901, COSV51719523; called by muse, mutect2
- NINL | c.4062C>T p.A1354= | Silent (SNP) | VAF 141/533 reads (26%) | catalogued as rs776524973; called by muse, mutect2, varscan2
- NOS2 | c.2730C>T p.I910= | Silent (SNP) | VAF 106/270 reads (39%) | called by muse, mutect2, varscan2
- OTOGL | c.2853C>T p.Y951= (on ENST00000547103; = p.Y942= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 67/283 reads (24%) | catalogued as rs770917728; called by muse, mutect2, varscan2
- PARD3 | c.39C>T p.V13= | Silent (SNP) | VAF 134/443 reads (30%) | catalogued as rs1241766266; called by muse, mutect2, varscan2
- PCDH11X | c.3630C>T p.S1210= | Silent (SNP) | VAF 204/450 reads (45%) | called by muse, mutect2, varscan2
- PCLO | c.6135G>T p.L2045= | Silent (SNP) | VAF 65/156 reads (42%) | catalogued as rs897450592; called by muse, mutect2, varscan2
- PGR | c.990C>T p.D330= | Silent (SNP) | VAF 145/522 reads (28%) | catalogued as COSV54805595; called by muse, varscan2
- PI15 | c.309T>C p.A103= | Silent (SNP) | VAF 86/460 reads (19%) | catalogued as COSV52640341; called by muse, mutect2, varscan2
- PIGK | c.1044A>G p.Q348= | Silent (SNP) | VAF 114/140 reads (81%) | catalogued as rs775599371, COSV63651061; called by muse, mutect2, varscan2
- PPFIA4 | c.3393C>T p.H1131= (on ENST00000447715; = p.H1132= on NM_001304331.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 217/691 reads (31%) | catalogued as rs747437590; called by muse, mutect2, varscan2
- PPIL2 | c.1134T>G p.S378= | Silent (SNP) | VAF 90/246 reads (37%) | called by muse, mutect2, varscan2
- PPM1G | c.159A>C p.T53= | Silent (SNP) | VAF 25/361 reads (7%) | called by muse, mutect2
- RBM12B | c.168C>T p.A56= | Silent (SNP) | VAF 19/357 reads (5%) | called by muse, mutect2
- SLC9B1 | c.894T>A p.I298= | Silent (SNP) | VAF 69/191 reads (36%) | called by muse, mutect2, varscan2
- STARD9 | c.13482T>G p.T4494= | Silent (SNP) | VAF 56/138 reads (41%) | called by muse, mutect2, varscan2
- STAT5A | c.606G>A p.T202= | Silent (SNP) | VAF 100/264 reads (38%) | catalogued as rs375378402; called by muse, mutect2, varscan2
- TFAP2A | c.132C>T p.A44= (on ENST00000482890; = p.A36= on NM_001032280.3) | Silent (SNP) | VAF 122/410 reads (30%) | called by muse, mutect2, varscan2
- TNKS1BP1 | c.2709C>T p.N903= | Silent (SNP) | VAF 271/454 reads (60%) | catalogued as rs769313015, COSV64102562; called by muse, mutect2, varscan2
- USP17L1 | c.648T>G p.T216= | Silent (SNP) | VAF 95/294 reads (32%) | called by muse, mutect2, varscan2
- ZCCHC4 | c.1359T>C p.H453= | Silent (SNP) | VAF 22/248 reads (9%) | called by muse, mutect2
- ZFHX4 | c.8847T>C p.S2949= | Silent (SNP) | VAF 181/424 reads (43%) | called by muse, mutect2, varscan2
- ZNF517 | c.1215C>T p.F405= | Silent (SNP) | VAF 57/926 reads (6%) | catalogued as rs745426670; called by muse, mutect2
- ZNF692 | c.57G>A p.Q19= | Silent (SNP) | VAF 191/850 reads (22%) | catalogued as rs771022929; called by muse, mutect2, varscan2
- ZNF726 | c.496A>C p.R166= | Silent (SNP) | VAF 62/139 reads (45%) | called by muse, mutect2, varscan2
- ZNF865 | c.609C>T p.C203= | Silent (SNP) | VAF 188/507 reads (37%) | catalogued as rs1220928798; called by muse, mutect2, varscan2
- AIFM3 | chr22:20964503 A>G | 5'Flank (SNP) | VAF 10/200 reads (5%) | called by muse, mutect2
- C2orf16 | chr2:27571544 G>T | 5'Flank (SNP) | VAF 90/318 reads (28%) | called by muse, mutect2, varscan2
- CA6 | c.259+2235A>G | Intron (SNP) | VAF 54/114 reads (47%) | called by muse, varscan2
- CFAP46 | c.966+46A>G | Intron (SNP) | VAF 95/382 reads (25%) | called by muse, mutect2, varscan2
- FAM219A | c.344+21G>A | Intron (SNP) | VAF 33/316 reads (10%) | called by muse, mutect2, varscan2
- KCNMA1 | c.2267-7510C>A | Intron (SNP) | VAF 15/382 reads (4%) | catalogued as COSV99695805; called by muse, mutect2
- KCNQ1 | c.1514+12839G>C | Intron (SNP) | VAF 176/288 reads (61%) | called by muse, mutect2, varscan2
- SLCO2A1 | chr3:133928661 G>T | 3'Flank (SNP) | VAF 143/372 reads (38%) | called by muse, mutect2, varscan2
- TRAF4 | c.*269T>G | 3'UTR (SNP) | VAF 84/202 reads (42%) | called by mutect2, varscan2
